Surgical pathology report (de-identified scan), TCGA case TCGA-4Z-AA7Y, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-4Z-AA7Y-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Bladder

I-"Bladder + prostate":

Papillary urothelial carcinoma of high grade, characterized as follows:

- . Measure of the longest axis: 3.5 cm
- . Infiltration up to detrusor muscle of the bladder.
- . Neural infiltration not observed.
- . Lymphatic vascular invasion not detected.
- . Sanguineous vascular invasion not detected.
- . Surgical margins free of neoplastic involvement.
- Nodular benign prostatic hyperplasia.
Nonspecific chronic prostatitis.
Lymph nodes free of neoplastic compromise (0/9).

II-"Left pelvic lymphadenectomy":

Free of neoplastic involvement (0/2).

III-"Right pelvic lymphadenectomy":

Free of neoplastic involvement (0/7).

ICD-O-3

Carcinoma, urothelial
papillary 8130/3

Site: ^{C67.2} Bladder, lateral wall
^{path} Bladder NOS C67.9

Q10318114

Criteria	hw 12/20/13	Yes	No
Dual/Synchronous Pathology Noted			

Source: NCI Genomic Data Commons file 351daa54-990c-4e58-972c-1f7c9dac5ada (TCGA-4Z-AA7Y.E0AF3F47-9EBB-4E83-B664-6C139C75D402.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).